Gene-level copy-number profile of tumor specimen ALCH-B1S5-TTP1-A from ALCHEMIST case ALCH-B1S5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.4 years (24,263 days).
Specimen ALCH-B1S5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cc0aafec-daac-4ce5-b87e-76f4e29eb9f6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1S5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/46d1c76c-af19-45b6-9f98-9f6577485215

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 642; copy number 2: 57,531; copy number 3: 85; copy number 4: 23; copy number 5: 17; copy number 7: 8; copy number 9: 4.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,020,120–1,056,118, 2 genes (within-gene range 0–2): AGRN, AL645608.5.
- chr2:127,048,027–127,107,288, 1 gene: BIN1.
- chr2:127,645,864–127,652,639, 1 gene (within-gene range 0–1): GPR17.
- chr3:52,316,319–52,445,103, 5 genes: DNAH1, PPP2R5CP, BAP1, PHF7, SEMA3G.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr5:180,601,506–180,649,624, 1 gene: FLT4.
- chr6:77,496,119–77,496,671, 1 gene: RPS6P7.
- chr8:70,506,251–70,506,818, 1 gene: AC022730.1.
- chr8:144,330,565–144,336,482, 1 gene: SCRT1.
- chr11:1,157,953–1,201,138, 1 gene: MUC5AC.
- chr11:2,159,779–2,173,138, 3 genes (within-gene range 0–2): INS, TH, MIR4686.
- chr11:67,395,210–67,395,311, 1 gene (within-gene range 0–2): RNU6-1238P.
- chr11:67,483,026–67,508,649, 4 genes: AIP, MIR6752, PITPNM1, CDK2AP2.
- chr12:122,920,951–122,982,913, 4 genes: ABCB9, OGFOD2, AC026362.1, ARL6IP4.
- chr12:131,894,622–131,923,150, 2 genes: ULK1, AC131009.4.
- chr12:132,200,436–132,201,287, 1 gene (within-gene range 0–1): AC138466.4.
- chr14:104,681,146–104,722,535, 2 genes (within-gene range 0–2): INF2, AL583722.3.
- chr14:105,140,982–105,168,824, 2 genes (within-gene range 0–2): JAG2, MIR6765.
- chr15:25,184,306–25,215,622, 18 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25.
- chr16:4,331,549–4,355,607, 2 genes (within-gene range 0–2): PAM16, AC012676.1.
- chr16:4,346,694–4,348,648, 1 gene (within-gene range 0–2): AC012676.5.
- chr17:81,395,457–81,481,570, 6 genes (within-gene range 0–1): BAHCC1, AC110285.6, MIR4740, MIR3186, AC110285.4, LINC01971.
- chr19:5,782,960–5,791,225, 3 genes: PRR22, AC011499.1, DUS3L.
- chr19:33,207,129–33,207,639, 1 gene (within-gene range 0–2): AC008738.7.
- chr20:3,227,417–3,245,382, 2 genes: SLC4A11, AL109976.1.
- chr20:25,248,085–25,298,012, 3 genes (within-gene range 0–2): PYGB, AL121772.2, AL121772.3.
- chr20:32,449,755–32,453,607, 1 gene (within-gene range 0–2): AL034550.1.
- chr20:58,689,131–58,719,238, 2 genes (within-gene range 0–2): NPEPL1, AL139349.1.
- chr22:35,336,721–35,336,799, 1 gene (within-gene range 0–2): MIR6069.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,453,030, 7 genes, copy number 7: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:19,024,090–19,131,167, 4 genes, copy number 9 (within-gene range 2–9): AL589182.1, GRAMD4P4, DUXAP9, AL589182.3.
- chr17:7,705,202–7,711,372, 1 gene, copy number 5: EFNB3.
- chr21:10,413,477–13,120,807, 12 genes, copy number 5: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 623. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
